Somatic mutation profile of tumor specimen MMRF_1648_1_BM_CD138pos (aliquot MMRF_1648_1_BM_CD138pos_T1_KBS5U_L04789) from MMRF case MMRF_1648, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.3 years (23,127 days).
Specimen MMRF_1648_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c819227d-ab83-4ee2-800b-591d2f1e823c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1648_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1648_1_PB_Whole_C3_KBS5U_L04802; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb30eed3-6cc5-40cb-ac72-3b24cb014fa3

The open-access MAF lists 96 somatic variants for this specimen: 35 protein-altering or splice-affecting, 21 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 22, Silent 21, Intron 11, RNA 3, 5'UTR 2, Splice Region 2, 5'Flank 2, Frame Shift Ins 1, Splice Site 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1436A>T p.D479V | Missense Mutation (SNP) | VAF 73/147 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705800, COSV66705888; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 60/111 reads (54%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANO2 | c.2002G>T p.G668C (on ENST00000356134 / NM_001278597.3; = p.G672C on NM_001278596.3) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200561749; called by muse, mutect2, varscan2
- DNAI3 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54001903; called by muse, mutect2, varscan2
- ENDOD1 | c.748A>G p.M250V | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.675); catalogued as rs1317736118; called by muse, mutect2, varscan2
- FAM160A2 | c.2839G>A p.V947I (on ENST00000449352 / NM_001098794.2; = p.V961I on NM_032127.4) | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.969); catalogued as COSV56410710; called by muse, mutect2
- FOXC1 | c.516_518dup p.R173dup | In Frame Ins (INS) | VAF 26/68 reads (38%) | catalogued as rs1183655796; called by mutect2, varscan2
- GFM1 | c.235-8G>A | Splice Region (SNP) | VAF 77/225 reads (34%) | catalogued as rs1412234808; called by muse, mutect2, varscan2
- IGHJ4 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 16/19 reads (84%) | PolyPhen benign (0.143); catalogued as rs371354427; called by muse, mutect2, varscan2
- IGHV2-70D | c.261G>T p.R87S | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs1415610196; called by muse, mutect2, varscan2
- IGKV1-6 | c.125C>T p.T42I | Missense Mutation (SNP) | VAF 98/100 reads (98%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as rs552944963; called by muse, varscan2
- INSRR | c.3751C>T p.R1251W | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs759533268, COSV63876673; called by muse, mutect2, varscan2
- KIF3C | c.2305C>G p.R769G | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as COSV53098587; called by muse, mutect2, varscan2
- LIMCH1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs868375839; called by muse, mutect2, varscan2
- LRGUK | c.1322A>G p.Y441C | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as rs141659989; called by muse, mutect2, varscan2
- PIM1 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 125/194 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.189); catalogued as COSV65166257, COSV65166391; called by muse, varscan2
- PROS1 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 60/227 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs765473908, COSV67774334, COSV67777309; called by muse, mutect2, varscan2
- PTGFR | c.97dup p.S33Ffs*27 | Frame Shift Ins (INS) | VAF 68/264 reads (26%) | catalogued as rs756672341; called by mutect2, varscan2
- ZBTB17 | c.1120A>G p.I374V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs868306166; called by muse, mutect2, varscan2
- CAPZA2 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- CLPX | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 304/533 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- COL15A1 | c.2689G>T p.G897* | Nonsense Mutation (SNP) | VAF 16/105 reads (15%) | called by mutect2, varscan2
- DACT2 | c.2197G>T p.A733S | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- DNAI3 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- EVC | c.2533C>G p.H845D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FSIP2 | c.8673T>G p.C2891W | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYO1G | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- MYOM3 | c.1804C>A p.L602I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- OR7A17 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- SEMA6D | c.447G>A p.R149= | Splice Region (SNP) | VAF 31/128 reads (24%) | called by muse, mutect2, varscan2
- STAG1 | c.3446+2T>C p.X1149_splice | Splice Site (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- SYNE2 | c.13339C>A p.Q4447K | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- USH2A | c.11560G>A p.V3854I | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- ZNF229 | c.1568G>A p.G523D | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ZNF419 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.023); called by mutect2, varscan2
- ADH6 | c.672T>C p.D224= | Silent (SNP) | VAF 36/158 reads (23%) | called by muse, mutect2, varscan2
- ALDOC | c.78G>A p.P26= | Silent (SNP) | VAF 10/147 reads (7%) | catalogued as rs377735389, COSV99256606; called by muse, mutect2
- ANKRD35 | c.522G>A p.Q174= | Silent (SNP) | VAF 8/210 reads (4%) | called by muse, mutect2
- BCAM | c.960G>A p.G320= | Silent (SNP) | VAF 37/151 reads (25%) | called by muse, mutect2, varscan2
- CELF4 | c.1062G>A p.A354= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs376891998; called by muse, mutect2, varscan2
- DENND1B | c.975A>G p.G325= | Silent (SNP) | VAF 63/172 reads (37%) | called by muse, mutect2, varscan2
- FAT4 | c.13069C>A p.R4357= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV58671941; called by mutect2, varscan2
- FNDC1 | c.3879C>A p.T1293= | Silent (SNP) | VAF 58/121 reads (48%) | catalogued as COSV99796403; called by muse, mutect2, varscan2
- H1-3 | c.399T>C p.A133= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs754813347; called by muse, mutect2, varscan2
- IGHV1-69D | c.267T>A p.I89= | Silent (SNP) | VAF 68/82 reads (83%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.123C>T p.C41= | Silent (SNP) | VAF 54/93 reads (58%) | catalogued as rs377265996; called by muse, varscan2
- MAP7D1 | c.2412C>T p.P804= | Silent (SNP) | VAF 41/134 reads (31%) | called by muse, mutect2, varscan2
- MECR | c.81C>T p.H27= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs1190745314, COSV55284650; called by muse, mutect2, varscan2
- MFHAS1 | c.2550C>T p.F850= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as rs774404630; called by muse, mutect2, varscan2
- NUP214 | c.5103A>G p.P1701= | Silent (SNP) | VAF 56/419 reads (13%) | catalogued as rs146467741; called by muse, mutect2, varscan2
- OTX2 | c.195C>A p.I65= (on ENST00000408990 / NM_172337.3; = p.I73= on NM_021728.4) | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as COSV59765878; called by muse, mutect2, varscan2
- PER2 | c.3195C>T p.L1065= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as rs1266653776; called by muse, mutect2, varscan2
- PRR36 | c.481C>A p.R161= | Silent (SNP) | VAF 13/355 reads (4%) | catalogued as COSV73401800; called by muse, mutect2
- SIM2 | c.1230T>C p.S410= | Silent (SNP) | VAF 88/173 reads (51%) | called by muse, mutect2, varscan2
- SVEP1 | c.1398T>C p.C466= | Silent (SNP) | VAF 67/326 reads (21%) | called by muse, mutect2, varscan2
- TMC5 | c.1398G>T p.L466= (on ENST00000396229 / NM_001105248.1; = p.L220= on NM_024780.5) | Silent (SNP) | VAF 19/91 reads (21%) | called by muse, mutect2, varscan2
- AHCTF1P1 | n.4884C>T | RNA (SNP) | VAF 45/143 reads (31%) | called by muse, mutect2, varscan2
- ANOS1 | c.*2538C>T | 3'UTR (SNP) | VAF 24/24 reads (100%) | called by muse, mutect2, varscan2
- BACH1 | c.*1198A>G | 3'UTR (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- BBOX1 | c.334+85A>T | Intron (SNP) | VAF 26/78 reads (33%) | called by muse, varscan2
- BMP1 | c.*291G>C | 3'UTR (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- CALML3 | c.*162C>G | 3'UTR (SNP) | VAF 88/202 reads (44%) | called by muse, mutect2, varscan2
- CLK2 | c.488-75del | Intron (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- CPNE9 | c.109+11C>T | Intron (SNP) | VAF 74/125 reads (59%) | called by muse, mutect2, varscan2
- CST9 | c.-52G>A | 5'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- DBI | c.-97C>A | 5'UTR (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- EBF3 | c.*845C>T | 3'UTR (SNP) | VAF 23/138 reads (17%) | called by muse, mutect2, varscan2
- FAM171B | c.*2901G>A | 3'UTR (SNP) | VAF 51/198 reads (26%) | called by muse, mutect2, varscan2
- FAM3B | c.*300T>G | 3'UTR (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- FGF9 | c.*1197dup | 3'UTR (INS) | VAF 97/203 reads (48%) | catalogued as rs956898361; called by mutect2, varscan2
- FKBP15 | c.*3498A>C | 3'UTR (SNP) | VAF 16/61 reads (26%) | catalogued as rs960964811; called by muse, mutect2
- GAPT | c.*1091T>C | 3'UTR (SNP) | VAF 62/199 reads (31%) | called by muse, mutect2, varscan2
- GIMAP4 | c.*29G>T | 3'UTR (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- IFT81 | c.1644+688T>C | Intron (SNP) | VAF 93/197 reads (47%) | called by muse, mutect2, varscan2
- LINC01235 | n.520G>A | RNA (SNP) | VAF 73/209 reads (35%) | called by muse, mutect2, varscan2
- LINC02876 | n.512G>C | RNA (SNP) | VAF 75/170 reads (44%) | called by muse, mutect2, varscan2
- LRR1 | chr14:49598273 A>G | 5'Flank (SNP) | VAF 18/28 reads (64%) | catalogued as rs1208805036; called by muse, mutect2
- LZTS2 | c.*655T>G | 3'UTR (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- MED31 | c.107-30C>G | Intron (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851186 C>T | 5'Flank (SNP) | VAF 91/145 reads (63%) | catalogued as rs775659782; called by muse, mutect2, varscan2
- MTHFD1L | c.2847+4660G>C | Intron (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- ORC5 | c.*308A>T | 3'UTR (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- RASGEF1C | c.-6-34C>T | Intron (SNP) | VAF 19/80 reads (24%) | called by muse, mutect2, varscan2
- SERPING1 | c.52-26dup | Intron (INS) | VAF 92/460 reads (20%) | called by mutect2, varscan2
- SETD4 | c.*992C>A | 3'UTR (SNP) | VAF 27/227 reads (12%) | called by muse, mutect2, varscan2
- SMARCD1 | c.*970T>C | 3'UTR (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- SNW1 | c.*156A>C | 3'UTR (SNP) | VAF 47/94 reads (50%) | called by muse, mutect2, varscan2
- SYBU | c.25-245T>C | Intron (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- SYMPK | c.*9G>A | 3'UTR (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- TOLLIP | c.*455G>A | 3'UTR (SNP) | VAF 58/217 reads (27%) | catalogued as rs375452637; called by muse, mutect2, varscan2
- TPT1 | c.400-52C>G | Intron (SNP) | VAF 38/176 reads (22%) | called by muse, mutect2, varscan2
- WDR72 | c.*1614A>G | 3'UTR (SNP) | VAF 31/173 reads (18%) | called by muse, mutect2, varscan2
- ZBTB44 | c.*3448G>T | 3'UTR (SNP) | VAF 35/128 reads (27%) | called by muse, mutect2, varscan2
- ZNF681 | c.*302A>T | 3'UTR (SNP) | VAF 16/177 reads (9%) | called by muse, mutect2, varscan2
- ZSCAN2 | c.406+2108A>G | Intron (SNP) | VAF 52/255 reads (20%) | catalogued as rs547781441; called by muse, mutect2, varscan2
- ZSWIM9 | c.*57G>A | 3'UTR (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
